Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FZ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FZ-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race)

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement: Anatomic Site: **Left Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **Frozen**

Container: **cryomold** Type of Procurement: **Radical mastectomy** Grade: **2**

T Stage: **2** N Stage: **2** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement: . . .

ICD-O-3

carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw 10/21/11

lw 10/21/11

Source: NCI Genomic Data Commons file ae62a534-0d55-4e6d-8093-28c827cd7530 (TCGA-AN-A0FZ.8CC70CDC-01EC-4E2B-84C1-F1C946602CCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).